Somatic mutation profile of tumor specimen 0DN1CZ from CCDI case PBCATY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.6 years (214 days).
Specimen 0DN1CZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 13232aa3-0477-40a6-93f7-42532bd130b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DN1B1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/48e38c53-2ea0-4130-8d5f-470fcb290693

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LRP1B | c.3069G>T p.W1023C | Missense Mutation (SNP) | VAF 80/1024 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67278294; called by muse, mutect2
- OBSCN | c.9250C>T p.R3084W | Missense Mutation (SNP) | VAF 46/936 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs780255462; called by muse, mutect2
- TRIM69 | c.89T>G p.V30G | Missense Mutation (SNP) | VAF 23/864 reads (3%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs781662713; called by muse, mutect2
- NUDCD3 | c.841G>C p.E281Q | Missense Mutation (SNP) | VAF 505/612 reads (83%) | SIFT tolerated (0.09); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- RPS4Y1 | c.533G>A p.G178D | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); called by muse, varscan2
- SLC35A5 | c.798A>G p.I266M | Missense Mutation (SNP) | VAF 84/1955 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); called by muse, mutect2
- SRRM4 | c.1458A>T p.R486S | Missense Mutation (SNP) | VAF 70/1068 reads (7%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.997); called by muse, mutect2
- WNK1 | c.5245A>C p.T1749P (on ENST00000315939 / NM_018979.4; = p.T1502P on NM_014823.3) | Missense Mutation (SNP) | VAF 44/1458 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.77); called by muse, mutect2
- PIK3CA | c.414C>T p.D138= | Silent (SNP) | VAF 88/1916 reads (5%) | catalogued as rs199543283; ClinVar: likely benign; called by muse, mutect2
- SYCP1 | c.1800+71T>A | Intron (SNP) | VAF 38/367 reads (10%) | called by muse, mutect2, varscan2
